Gene-level copy-number profile of tumor specimen TCGA-A2-A0EV-01A from TCGA case TCGA-A2-A0EV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 80.2 years (29,285 days).
Specimen TCGA-A2-A0EV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2ee9b4c3-15a5-4766-b762-ad8a96dc08f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0EV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af9b2796-25c2-4f16-a8ea-0d4e33dc30ab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 537; copy number 2: 8,146; copy number 3: 29,903; copy number 4: 14,132; copy number 5: 4,051; copy number 6: 2,943; copy number 7: 103; copy number 9: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0EV-01A-11D-A036-01): tumor purity 0.45, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 105 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,369,540–175,397,348, 2 genes, copy number 9: MIR4789, RNU6-1233P.
- chr5:120,464,300–127,290,731, 90 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:52,390,515–54,478,168, 13 genes, copy number 7: LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3.

Autosomal genes at a single copy (total copy number 1): 537. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
